Somatic mutation profile of tumor specimen TCGA-ZF-AA54-01A (aliquot TCGA-ZF-AA54-01A-11D-A391-08) from TCGA case TCGA-ZF-AA54, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 71.5 years (26,128 days).
Specimen TCGA-ZF-AA54-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fdab99d3-963c-47f0-a941-a41b05538970.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZF-AA54-10A (Blood Derived Normal), aliquot TCGA-ZF-AA54-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8c3e91e8-dd09-4f4a-86b9-6ec6f04f4e0a

The open-access MAF lists 197 somatic variants for this specimen: 152 protein-altering or splice-affecting, 40 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 124, Silent 40, Nonsense Mutation 15, Splice Site 6, Frame Shift Del 3, Intron 3, Splice Region 2, Nonstop Mutation 1, In Frame Del 1, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 73/132 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AARS2 | c.358G>C p.D120H | Missense Mutation (SNP) | VAF 46/140 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55114352; called by muse, mutect2, varscan2
- AASDH | c.755C>T p.A252V | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV52705674; called by muse, mutect2, varscan2
- ABCD1 | c.1778G>A p.G593E | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.976); catalogued as COSV54384148, COSV99497791; called by muse, mutect2, varscan2
- ACSS3 | c.506A>G p.D169G | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54088891; called by muse, mutect2, varscan2
- ACTR1B | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 88/207 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as COSV56703004; called by muse, mutect2, varscan2
- ADAM10 | c.667C>G p.Q223E | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs771723938, COSV53050842; called by muse, varscan2
- ADAM10 | c.592C>G p.Q198E | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53050850; called by muse, varscan2
- ADAM19 | c.1500G>C p.Q500H | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV57427357; called by muse, mutect2, varscan2
- ADCY10 | c.3088A>C p.I1030L | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as COSV63239901; called by muse, mutect2, varscan2
- ADGRF1 | c.2191G>C p.D731H | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV51944669, COSV51945500; called by muse, mutect2, varscan2
- AGGF1 | c.948G>A p.M316I | Missense Mutation (SNP) | VAF 38/169 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV57228514; called by muse, mutect2, varscan2
- AHCTF1 | c.1281G>C p.Q427H (on ENST00000366508; = p.Q401H on NM_015446.5) | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58248536; called by muse, mutect2, varscan2
- AKAP11 | c.4856C>G p.S1619C | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.911); catalogued as COSV50295381; called by muse, mutect2, varscan2
- AKAP6 | c.838G>A p.D280N | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.326); catalogued as COSV55210744; called by muse, mutect2, varscan2
- AKAP6 | c.5497A>T p.S1833C | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV55210757; called by muse, mutect2, varscan2
- ANK3 | c.1664G>C p.G555A | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as COSV55052478; called by muse, mutect2, varscan2
- ANKRD11 | c.4422G>C p.E1474D | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV56359082; called by muse, mutect2, varscan2
- ARHGAP30 | c.74A>G p.H25R | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as COSV63512393; called by muse, varscan2
- ARPP21 | c.851G>C p.R284T | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774083682, COSV51795374; called by muse, mutect2, varscan2
- ASXL2 | c.1031C>G p.S344* | Nonsense Mutation (SNP) | VAF 24/64 reads (38%) | catalogued as COSV55460371; called by muse, mutect2, varscan2
- ATP5MD | c.53A>G p.Y18C | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1564749317, COSV58915506; called by muse, mutect2, varscan2
- BLM | c.983C>G p.S328C | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV61923357; called by muse, mutect2, varscan2
- C11orf94 | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs1191885692, COSV53797395; called by muse, mutect2, varscan2
- C1GALT1C1 | c.867G>C p.M289I | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as COSV58973696, COSV58973966, COSV58974307; called by muse, mutect2, varscan2
- C1QBP | c.466G>T p.E156* | Nonsense Mutation (SNP) | VAF 26/60 reads (43%) | catalogued as COSV99852140; called by muse, mutect2, varscan2
- CADM2 | c.1109T>C p.I370T (on ENST00000407528 / NM_001167674.2; = p.I372T on NM_153184.4) | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1230785696, COSV67367714; called by muse, mutect2, varscan2
- CALML6 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.493); catalogued as rs201706077, COSV57069124; called by muse, mutect2, varscan2
- CCAR1 | c.637C>G p.Q213E | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as COSV56268885, COSV56272962; called by muse, mutect2, varscan2
- CCAR1 | c.767C>G p.S256C | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.436); catalogued as rs1479373070, COSV56268900, COSV56269438; called by muse, varscan2
- CCAR1 | c.1271G>A p.R424K | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56268910; called by muse, mutect2, varscan2
- CD81 | c.109C>A p.H37N | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55132634; called by muse, mutect2, varscan2
- CDH12 | c.607C>T p.L203F | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV66392420; called by muse, mutect2, varscan2
- CDH12 | c.46G>C p.D16H | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV101203390, COSV66397818; called by muse, mutect2, varscan2
- CDH19 | c.1746C>G p.C582W | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50956764, COSV50967294; called by muse, mutect2, varscan2
- CDH4 | c.685A>G p.M229V | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.422); catalogued as COSV64649637; called by muse, mutect2
- CGN | c.2656G>T p.E886* | Nonsense Mutation (SNP) | VAF 10/36 reads (28%) | catalogued as COSV99641960; called by muse, varscan2
- CHD6 | c.3521C>T p.S1174L | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.074); catalogued as COSV58555905; called by muse, mutect2, varscan2
- CNIH4 | c.194C>G p.S65* | Nonsense Mutation (SNP) | VAF 34/115 reads (30%) | catalogued as COSV100836977; called by muse, mutect2, varscan2
- CNTNAP1 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as rs1283843197, COSV52849254; called by muse, mutect2, varscan2
- CRACD | c.83C>G p.S28* | Nonsense Mutation (SNP) | VAF 15/56 reads (27%) | catalogued as COSV99948646; called by muse, mutect2, varscan2
- CREBRF | c.1274C>T p.S425L | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as rs935447459, COSV51632494, COSV99755602; called by muse, mutect2, varscan2
- CROT | c.677A>G p.K226R | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1028693396, COSV58973747; called by muse, mutect2, varscan2
- DACT1 | c.1558C>G p.P520A | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.79); PolyPhen benign (0.169); catalogued as COSV60020264; called by muse, mutect2, varscan2
- DDX10 | c.1755A>C p.E585D | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.237); catalogued as COSV59433479; called by muse, mutect2, varscan2
- DLG4 | c.333C>T p.L111= (on ENST00000399506 / NM_001321075.3; = p.L154= on NM_001365.4) | Splice Region (SNP) | VAF 29/70 reads (41%) | catalogued as COSV57237641; called by muse, mutect2, varscan2
- DNAJC10 | c.2197C>G p.Q733E | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.021); catalogued as COSV51136788; called by muse, mutect2, varscan2
- DSEL | c.3381G>T p.L1127F | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59490661; called by muse, mutect2
- EEF2K | c.1942A>T p.T648S | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs1176536796, COSV53780510; called by muse, mutect2, varscan2
- EEFSEC | c.1790G>C p.*597Sext*51 | Nonstop Mutation (SNP) | VAF 17/87 reads (20%) | catalogued as COSV99629667; called by muse, mutect2, varscan2
- FAM20B | c.691C>G p.L231V | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.25); catalogued as COSV55379827; called by muse, mutect2, varscan2
- FMNL3 | c.1003G>T p.E335* | Nonsense Mutation (SNP) | VAF 31/57 reads (54%) | catalogued as COSV99525687; called by muse, mutect2, varscan2
- FRY | c.1583G>A p.G528E | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV66568284; called by mutect2, varscan2
- FZD9 | c.925G>C p.E309Q | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV60669933; called by muse, mutect2, varscan2
- GABRG1 | c.134A>T p.E45V | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.725); catalogued as rs1048474882, COSV54952380; called by muse, mutect2
- GALNTL5 | c.1083C>G p.I361M | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV67179777, COSV67181171; called by muse, mutect2, varscan2
- GBP1 | c.974C>G p.S325* | Nonsense Mutation (SNP) | VAF 39/113 reads (35%) | catalogued as COSV100976223; called by muse, mutect2, varscan2
- GON4L | c.4414G>A p.E1472K | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.321); catalogued as COSV55191323; called by muse, mutect2, varscan2
- GRHL2 | c.879C>G p.I293M | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.954); catalogued as COSV52547095; called by muse, mutect2, varscan2
- GYS2 | c.722G>A p.R241Q | Missense Mutation (SNP) | VAF 26/187 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as rs151087668; called by muse, mutect2, varscan2
- H2BC11 | c.340G>T p.E114* | Nonsense Mutation (SNP) | VAF 49/158 reads (31%) | catalogued as COSV100345616, COSV60362089, COSV60362099; called by muse, mutect2, varscan2
- HEATR1 | c.3805G>A p.D1269N | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.521); catalogued as COSV100857805, COSV63980491; called by muse, mutect2, varscan2
- HEATR1 | c.125A>G p.D42G | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.399); catalogued as COSV63979379; called by muse, mutect2, varscan2
- HHIPL2 | c.1371G>C p.L457F | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.197); catalogued as COSV58564457; called by muse, mutect2, varscan2
- IARS2 | c.2164G>A p.D722N | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV56958934; called by muse, mutect2, varscan2
- INHA | c.299G>C p.R100T | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as COSV54717120; called by muse, mutect2, varscan2
- IRGC | c.530C>T p.T177M | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as rs1222017626, COSV54983691; called by muse, mutect2, varscan2
- ITFG1 | c.1115C>A p.A372E | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.242); catalogued as COSV57746930; called by muse, mutect2, varscan2
- KATNA1 | c.235G>C p.D79H | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs1297804127, COSV59502073; called by muse, mutect2, varscan2
- KIF9 | c.1966G>T p.E656* (on ENST00000265529 / NM_001377474.1; = p.E591* on NM_022342.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 18/63 reads (29%) | catalogued as COSV99646405; called by muse, mutect2, varscan2
- KIFC1 | c.161G>C p.R54T | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as COSV65737461; called by muse, mutect2, varscan2
- KLHDC3 | c.715C>T p.R239C | Missense Mutation (SNP) | VAF 49/169 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55064007; called by muse, mutect2, varscan2
- KLHL25 | c.819G>C p.K273N | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.121); catalogued as COSV61994750; called by muse, mutect2, varscan2
- LAMA1 | c.2989+1G>T p.X997_splice | Splice Site (SNP) | VAF 18/48 reads (38%) | catalogued as COSV67535089, COSV67544300; called by muse, mutect2, varscan2
- LAMB3 | c.797C>T p.S266F | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.601); catalogued as COSV61916304; called by muse, mutect2, varscan2
- LAMB3 | c.610C>T p.Q204* | Nonsense Mutation (SNP) | VAF 11/67 reads (16%) | catalogued as COSV100620117; called by muse, mutect2, varscan2
- LATS1 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 62/165 reads (38%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.027); catalogued as COSV53589183; called by muse, mutect2, varscan2
- LMOD3 | c.1238A>G p.Q413R | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV70455947; called by muse, mutect2, varscan2
- LRRC8C | c.2216del p.N739Tfs*19 | Frame Shift Del (DEL) | VAF 16/144 reads (11%) | catalogued as COSV65001046; called by mutect2, pindel, varscan2
- MACF1 | c.12136-1G>A p.X4046_splice (on ENST00000372915; = p.X1979_splice on NM_012090.5) | Splice Site (SNP) | VAF 19/134 reads (14%) | catalogued as COSV57116570; called by muse, mutect2, varscan2
- MAP1LC3A | c.9G>A p.M3I | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs1331256249, COSV66381610; called by muse, mutect2, varscan2
- MCTP2 | c.1880T>C p.I627T | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV59142840; called by muse, mutect2, varscan2
- MINPP1 | c.974G>C p.R325T | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV100916738; called by muse, mutect2
- MSTO1 | c.902C>T p.S301F | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1369814493, COSV55471744; called by muse, mutect2, varscan2
- MYCBP2 | c.11741T>C p.M3914T (on ENST00000357337; = p.M3952T on NM_015057.5) | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV62015116; called by muse, mutect2, varscan2
- MYH7B | c.1662C>A p.F554L | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV53418424; called by muse, mutect2, varscan2
- MYH7B | c.2848G>C p.E950Q | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53418433; called by muse, mutect2, varscan2
- MYH9 | c.5041G>A p.E1681K | Missense Mutation (SNP) | VAF 103/175 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs1458660141, COSV53383422; called by muse, mutect2, varscan2
- MYO9A | c.1047G>C p.E349D | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV61849580; called by muse, mutect2, varscan2
- MYZAP | c.1343G>C p.R448T (on ENST00000267853 / NM_001018100.5; = p.R420T on NM_152451.7) | Missense Mutation (SNP) | VAF 26/168 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.603); catalogued as COSV51089602; called by muse, mutect2, varscan2
- NIN | c.2497C>G p.L833V | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV55386476; called by muse, mutect2, varscan2
- NLRP10 | c.1824G>C p.L608F | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV60779826; called by muse, mutect2, varscan2
- NLRP4 | c.2917G>C p.E973Q | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.946); catalogued as COSV56707850; called by muse, mutect2, varscan2
- NT5DC2 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.088); catalogued as rs762876731, COSV58732200; called by muse, mutect2, varscan2
- NUP205 | c.3694C>T p.L1232F | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV53657534; called by muse, mutect2, varscan2
- OOEP | c.74G>A p.R25H | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.272); catalogued as rs758304583, COSV64859110; called by muse, mutect2, varscan2
- PCDH11X | c.3635C>T p.P1212L | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.231); catalogued as COSV53456660; called by muse, mutect2, varscan2
- PCDHB10 | c.907C>G p.L303V | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53377524; called by muse, mutect2, varscan2
- PCED1A | c.444-1G>C p.X148_splice | Splice Site (SNP) | VAF 71/220 reads (32%) | catalogued as COSV62313542; called by muse, mutect2, varscan2
- PEAK1 | c.705G>C p.E235D | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.034); catalogued as COSV56933537; called by muse, mutect2, varscan2
- PGPEP1 | c.438-1G>C p.X146_splice | Splice Site (SNP) | VAF 12/36 reads (33%) | catalogued as COSV53252259; called by muse, mutect2, varscan2
- PI4KB | c.2117C>T p.S706L (on ENST00000368873 / NM_001369623.1; = p.S718L on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV55016529; called by muse, mutect2, varscan2
- PLEKHH2 | c.1918G>C p.D640H | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.396); catalogued as COSV56751995; called by muse, mutect2, varscan2
- POMGNT2 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.037); catalogued as COSV60952897, COSV99048913; called by muse, mutect2, varscan2
- PPM1E | c.904C>T p.P302S | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV57572848; called by muse, mutect2, varscan2
- PPP2R3A | c.1106T>C p.I369T | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV53862179; called by muse, mutect2, varscan2
- PRKD3 | c.2140C>T p.P714S | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV99305751; called by muse, mutect2
- PSG1 | c.711G>A p.P237= | Splice Region (SNP) | VAF 50/260 reads (19%) | catalogued as rs4030951, COSV54946847, COSV54957573; called by muse, mutect2, varscan2
- PTPN13 | c.5182C>G p.L1728V (on ENST00000411767 / NM_080683.3; = p.L1709V on NM_006264.3) | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV57405416; called by muse, mutect2, varscan2
- RAD50 | c.1811C>T p.S604F | Missense Mutation (SNP) | VAF 38/157 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.143); catalogued as COSV54750005; called by muse, mutect2, varscan2
- RANBP3L | c.1228C>T p.Q410* | Nonsense Mutation (SNP) | VAF 27/95 reads (28%) | catalogued as COSV99683605; called by muse, mutect2, varscan2
- RASAL2 | c.2520G>C p.Q840H | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV62712326; called by muse, mutect2, varscan2
- RB1CC1 | c.173G>C p.R58T | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV50245807, COSV99212959; called by muse, varscan2
- RNF152 | c.581C>G p.S194C | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.984); catalogued as COSV100455010, COSV57183932; called by muse, mutect2
- RNF24 | c.166G>C p.E56Q | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.954); catalogued as COSV60191469; called by muse, mutect2, varscan2
- RPGRIP1L | c.614G>A p.R205K | Missense Mutation (SNP) | VAF 63/139 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as COSV50904542; called by muse, mutect2, varscan2
- RPGRIP1L | c.485G>C p.R162T | Missense Mutation (SNP) | VAF 83/201 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV50904565, COSV50906526; called by muse, mutect2, varscan2
- RPGRIP1L | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 64/177 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV50904721; called by muse, mutect2, varscan2
- SENP7 | c.2699-1G>C p.X900_splice | Splice Site (SNP) | VAF 8/45 reads (18%) | catalogued as COSV58610522; called by muse, mutect2, varscan2
- SERPINA3 | c.122G>C p.R41P | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs867783314, COSV67585389, COSV67585802; called by muse, mutect2, varscan2
- SHF | c.343C>G p.Q115E | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.028); catalogued as COSV52050087; called by muse, mutect2, varscan2
- SLC15A3 | c.1388C>G p.P463R | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50003785; called by muse, mutect2, varscan2
- SLC34A3 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.451); catalogued as rs774035480, COSV63186841; called by muse, mutect2, varscan2
- SLC9A4 | c.295G>C p.E99Q | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV54832383; called by muse, mutect2, varscan2
- SMG7 | c.668C>T p.S223F | Missense Mutation (SNP) | VAF 57/183 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as COSV61630624; called by muse, mutect2, varscan2
- SORBS3 | c.1033G>A p.D345N | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.796); catalogued as rs749196061, COSV53552483; called by muse, mutect2, varscan2
- SPATA22 | c.1054G>C p.E352Q | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV52152221; called by muse, mutect2, varscan2
- STON2 | c.197C>G p.S66W | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as COSV50843465; called by muse, mutect2, varscan2
- STRA6 | c.1263G>A p.M421I | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV60585530; called by muse, mutect2, varscan2
- SYNE1 | c.3678G>C p.K1226N (on ENST00000367255 / NM_182961.4; = p.K1233N on NM_033071.3) | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.377); catalogued as COSV54954182, COSV54961759; called by muse, mutect2, varscan2
- SYNGAP1 | c.296-1G>A p.X99_splice | Splice Site (SNP) | VAF 9/28 reads (32%) | catalogued as COSV53380171; called by muse, mutect2, varscan2
- SYNGAP1 | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as rs1217649207, COSV53380190; called by muse, mutect2, varscan2
- TAF3 | c.30G>C p.L10F | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV60205285; called by muse, mutect2, varscan2
- TBC1D26 | c.70G>C p.E24Q | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.443); catalogued as COSV101343656; called by muse, mutect2, varscan2
- TEDDM1 | c.776C>A p.S259* | Nonsense Mutation (SNP) | VAF 26/74 reads (35%) | catalogued as COSV100842922; called by muse, mutect2, varscan2
- THBS2 | c.3440G>T p.G1147V | Missense Mutation (SNP) | VAF 61/266 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64678205, COSV64681708; called by muse, mutect2, varscan2
- TP53 | c.859G>T p.E287* | Nonsense Mutation (SNP) | VAF 14/32 reads (44%) | catalogued as CM044948, COSV52679410, COSV52730707, COSV52765316; called by muse, mutect2, varscan2
- TRIM24 | c.2980G>C p.E994Q (on ENST00000343526 / NM_015905.3; = p.E960Q on NM_003852.4) | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.437); catalogued as COSV58971120; called by muse, mutect2, varscan2
- TRIM71 | c.1963C>T p.R655* | Nonsense Mutation (SNP) | VAF 7/51 reads (14%) | catalogued as COSV101070385, COSV67470430; called by muse, mutect2, varscan2
- TSC1 | c.555del p.Y185* | Frame Shift Del (DEL) | VAF 27/69 reads (39%) | catalogued as COSV53765068, COSV53765773, COSV53771625, COSV53775014; called by mutect2, pindel, varscan2
- USH2A | c.10286G>A p.R3429K | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV56354589; called by muse, mutect2, varscan2
- USH2A | c.9959G>A p.G3320D | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.826); catalogued as rs754315038, CM165982, COSV56354605; called by muse, mutect2, varscan2
- USP9X | c.4354G>A p.E1452K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV61068057; called by muse, mutect2
- VPS13C | c.5110C>T p.Q1704* (on ENST00000644861 / NM_020821.3; = p.Q1661* on NM_017684.5) | Nonsense Mutation (SNP) | VAF 49/154 reads (32%) | catalogued as rs1258310284, COSV51427682, COSV99827376; called by muse, mutect2, varscan2
- VPS45 | c.864G>C p.K288N | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs1553799475, COSV64887472; called by muse, mutect2, varscan2
- VPS50 | c.269G>C p.R90T | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.991); catalogued as COSV52494043, COSV99298419; called by muse, mutect2, varscan2
- WDR7 | c.3452G>A p.R1151Q | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.921); catalogued as COSV54351268; called by muse, mutect2, varscan2
- ZBTB40 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs1434996110, COSV65145087; called by muse, mutect2, varscan2
- ZCCHC4 | c.136C>G p.L46V | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57180988; called by muse, mutect2, varscan2
- ZNF638 | c.5189C>G p.P1730R | Missense Mutation (SNP) | VAF 53/137 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs747112326, COSV52485176; called by muse, mutect2, varscan2
- C1QTNF9 | c.651del p.D218Ifs*54 | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | called by mutect2, varscan2
- TNKS | c.48_50del p.Q17del | In Frame Del (DEL) | VAF 12/60 reads (20%) | called by pindel, varscan2
- AC008397.2 | c.1683G>A p.T561= | Silent (SNP) | VAF 33/93 reads (35%) | catalogued as rs778842682, COSV53206336; called by muse, mutect2, varscan2
- ADAR | c.141C>G p.L47= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as COSV52714049; called by muse, mutect2, varscan2
- AP2M1 | c.1212G>A p.L404= | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as COSV53047686; called by muse, mutect2, varscan2
- ASB11 | c.405C>G p.L135= | Silent (SNP) | VAF 51/104 reads (49%) | catalogued as COSV60354846, COSV60355672; called by muse, mutect2, varscan2
- CIB2 | c.90G>T p.L30= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV51948089; called by muse, mutect2, varscan2
- COBL | c.174G>A p.L58= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as COSV54336958, COSV54342947; called by muse, mutect2, varscan2
- CYP20A1 | c.588G>A p.K196= | Silent (SNP) | VAF 66/122 reads (54%) | catalogued as COSV61909325; called by muse, mutect2, varscan2
- DIPK2A | c.369G>A p.Q123= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs1464681361, COSV59856901; called by muse, mutect2, varscan2
- EPHA5 | c.1731G>T p.V577= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as COSV56639638, COSV56670948; called by muse, mutect2, varscan2
- EPHX2 | c.1614C>G p.L538= | Silent (SNP) | VAF 41/139 reads (29%) | catalogued as COSV66844523; called by muse, mutect2, varscan2
- FERMT3 | c.630C>T p.L210= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV99656330; called by muse, mutect2
- IGHV3-21 | c.174G>A p.Q58= | Silent (SNP) | VAF 66/264 reads (25%) | catalogued as rs1567201940; called by muse, varscan2
- IGKV6D-41 | c.21C>T p.F7= | Silent (SNP) | VAF 38/86 reads (44%) | called by muse, mutect2, varscan2
- IRX1 | c.1158C>G p.L386= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV100116255; called by muse, mutect2
- LPP | c.1374T>A p.A458= | Silent (SNP) | VAF 35/92 reads (38%) | catalogued as COSV57086052; called by muse, mutect2, varscan2
- MSH3 | c.2772A>G p.A924= | Silent (SNP) | VAF 48/158 reads (30%) | catalogued as COSV54149099; called by muse, mutect2, varscan2
- NALCN | c.3720T>C p.P1240= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV51928612; called by muse, mutect2, varscan2
- NFXL1 | c.558C>G p.P186= | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as COSV100217031, COSV61198595; called by muse, mutect2, varscan2
- NLRP13 | c.3039G>C p.L1013= | Silent (SNP) | VAF 43/148 reads (29%) | catalogued as COSV61621122; called by muse, mutect2, varscan2
- OR2T4 | c.751T>C p.L251= | Silent (SNP) | VAF 66/178 reads (37%) | catalogued as COSV100822676, COSV63543727; called by muse, mutect2, varscan2
- PAOX | c.834C>T p.F278= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as COSV53371941, COSV53374159; called by muse, mutect2, varscan2
- PPARGC1B | c.2280C>T p.I760= | Silent (SNP) | VAF 48/157 reads (31%) | catalogued as COSV58528344; called by muse, varscan2
- PSPC1 | c.1359T>C p.T453= | Silent (SNP) | VAF 11/173 reads (6%) | called by muse, mutect2
- PSPH | c.345T>C p.I115= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as COSV51910196; called by muse, mutect2, varscan2
- SLC12A9 | c.330C>A p.R110= | Silent (SNP) | VAF 17/99 reads (17%) | catalogued as COSV51932521; called by muse, mutect2, varscan2
- SLC34A3 | c.1224C>T p.I408= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV63186844; called by muse, mutect2, varscan2
- SORL1 | c.2284C>T p.L762= | Silent (SNP) | VAF 58/130 reads (45%) | catalogued as rs374434445, COSV52752451; called by muse, mutect2, varscan2
- SPART | c.669G>A p.L223= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as rs996610077, COSV100768868, COSV62084711; called by muse, mutect2, varscan2
- SPATA22 | c.921G>A p.L307= | Silent (SNP) | VAF 39/91 reads (43%) | catalogued as COSV52152227; called by muse, mutect2, varscan2
- SPTAN1 | c.898C>T p.L300= | Silent (SNP) | VAF 57/117 reads (49%) | catalogued as COSV63986395; called by muse, mutect2, varscan2
- SULT6B1 | c.618G>C p.L206= (on ENST00000535679 / NM_001367551.1; = p.L168= on NM_001032377.2) | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV53194077; called by muse, mutect2
- TGM7 | c.1602G>A p.Q534= | Silent (SNP) | VAF 42/102 reads (41%) | catalogued as COSV71772700; called by muse, mutect2, varscan2
- TMTC1 | c.828G>A p.Q276= (on ENST00000539277 / NM_001193451.2; = p.Q168= on NM_175861.3) | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV55479004; called by muse, mutect2
- TTC37 | c.2748C>G p.L916= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV62454414; called by muse, mutect2, varscan2
- TTN | c.28680G>A p.E9560= (on ENST00000591111; = p.E8633= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 45/94 reads (48%) | catalogued as COSV59984582; called by muse, mutect2, varscan2
- U2AF2 | c.306C>T p.I102= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV58273267; called by muse, mutect2, varscan2
- WNK4 | c.3147C>G p.L1049= | Silent (SNP) | VAF 22/47 reads (47%) | catalogued as COSV55903191, COSV55909829; called by muse, mutect2, varscan2
- ZCWPW1 | c.864C>T p.N288= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV61248671; called by muse, mutect2, varscan2
- ZNF496 | c.1164C>T p.S388= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV54175855; called by muse, mutect2, varscan2
- ZSWIM2 | c.210G>A p.P70= | Silent (SNP) | VAF 53/94 reads (56%) | catalogued as rs765189432, COSV54574784; called by muse, mutect2, varscan2
- ANKRD54 | chr22:37847718 G>A | 5'Flank (SNP) | VAF 29/65 reads (45%) | catalogued as COSV99316370; called by muse, mutect2, varscan2
- LCMT1 | c.114-2451A>G | Intron (SNP) | VAF 10/20 reads (50%) | catalogued as rs1222179731; called by muse, mutect2, varscan2
- RPSA | c.498+101G>A | Intron (SNP) | VAF 20/72 reads (28%) | catalogued as COSV100088039; called by muse, mutect2, varscan2
- SLC44A2 | c.2015-320A>G | Intron (SNP) | VAF 4/18 reads (22%) | catalogued as rs1242783282, COSV59836172; called by muse, varscan2
- SYNE2 | chr14:64227598 G>C | 3'Flank (SNP) | VAF 36/180 reads (20%) | catalogued as COSV59946621; called by muse, mutect2, varscan2
